Somatic mutation profile of tumor specimen TARGET-30-PAUELT-01A (aliquot TARGET-30-PAUELT-01A-01D) from TARGET case TARGET-30-PAUELT, project TARGET-NBL (Neuroblastoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Neuroblastoma, NOS; Tissue or organ of origin: Kidney, NOS; Age at diagnosis: 4.5 years (1,633 days).
Specimen TARGET-30-PAUELT-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) a61e6ae4-352f-473f-8446-c88a25ccce54.targeted_sequencing.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-30-PAUELT-10A (Blood Derived Normal), aliquot TARGET-30-PAUELT-10A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/cd2123f6-ba69-4f91-a799-9b74aea5844a

The open-access MAF lists 2 somatic variants for this specimen: 1 protein-altering or splice-affecting, 1 silent.
By variant classification: Silent 1, Missense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PTPN11 | c.1520C>A p.T507K | Missense Mutation (SNP) | VAF 47/124 reads (38%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.93); catalogued as rs886039463, CM090464, COSV104418166, COSV61005528; ClinVar: pathogenic; called by muse, mutect2, varscan2
- EVC | c.1389G>T p.T463= | Silent (SNP) | VAF 32/65 reads (49%) | catalogued as COSV53829283, COSV53834148; called by muse, mutect2, varscan2
